FM case AD17716 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/ddae3405-b084-4013-9863-27fc2ab68893

Female, 67.8 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the thorax. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
